TARGET case TARGET-15-SJMPAL042799 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bd93093b-3e51-419e-aef2-bb325d3c1292

Demographics
Sex at birth: male; Age at index: 11 years; Vital status: Dead; Days to death: 486 days (1.3 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 11.2 years (4,090 days); Year of diagnosis: 2009; Days to last follow up: 486 days (1.3 years).

Follow-up (1 entry)
- Days to follow up: 486 days (1.3 years); Event-free: no event (relapse, second malignancy or death) recorded through day 486; Year of follow up: 2010.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 335 ×10³/µL.

Biospecimens (2 samples)
- Samples TARGET-15-SJMPAL042799-09A, TARGET-15-SJMPAL042799-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 486
- Protocol: Japan (TCCSG)
- WBC at Diagnosis: 335.2
- Initial Therapy: AML
- Karyotype: 46,Y,der(X)add(X)(p11.2)add(X)(q22),t(6;9)(q15;p24) [20]
- WHO ALAL Classification: NOS (T/B/M)
- WHO Dx: NOS (T/B/M)
